Gene-level copy-number profile of tumor specimen TARGET-10-PATGYH-09A from TARGET case TARGET-10-PATGYH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.3 years (5,959 days).
Specimen TARGET-10-PATGYH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.089f607d-f67f-59b4-9661-9f48dd7b1245.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATGYH-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate.
https://portal.gdc.cancer.gov/files/694c1c31-e194-44f7-87b5-ce896747e059

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 2,598; copy number 2: 57,599; copy number 3: 17; copy number 4: 1; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,340,998, 14 genes: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes: TRGV5P, TRGV5, TRGV4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:43,179,501–43,181,193, 1 gene, copy number 5: AL138709.1.

Autosomal genes at a single copy (total copy number 1): 211. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
